Somatic mutation profile of tumor specimen TCGA-OR-A5JU-01A (aliquot TCGA-OR-A5JU-01A-11D-A30A-10) from TCGA case TCGA-OR-A5JU, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 58.3 years (21,292 days).
Specimen TCGA-OR-A5JU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b989fc7-1324-4a14-ae1c-8bb0ceed29cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JU-10A (Blood Derived Normal), aliquot TCGA-OR-A5JU-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ff6f557-37db-4fbc-ad02-bdeb7f50203b

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Splice Site 2, Silent 2, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L2 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs145837129; called by muse, mutect2, varscan2
- HSPG2 | c.4450G>T p.A1484S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1220618419; called by muse, mutect2
- KIF27 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs150984973; called by muse, mutect2
- RAD9A | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs549233956, COSV57237338, COSV57237625; called by muse, mutect2
- SORCS1 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53899611; called by muse, mutect2
- ZFP36L1 | c.725C>G p.T242S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.817); catalogued as COSV60547626; called by muse, mutect2, varscan2
- CDX4 | c.854G>T p.*285Lext*46 | Nonstop Mutation (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- KCNT2 | c.2057A>G p.H686R | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LNPK | c.242T>G p.F81C | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LRRC71 | c.1518G>T p.K506N | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); called by muse, mutect2
- MEAF6 | c.91-2A>G p.X31_splice | Splice Site (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- NLGN1 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2
- PCDH15 | c.5470T>A p.S1824T | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.013); called by muse, mutect2
- RBPJL | c.1020+1G>C p.X340_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- TTC17 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBN2 | c.1954A>G p.K652E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USF3 | c.2665T>C p.S889P | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- APOB | c.6216A>T p.P2072= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- LPA | c.3489C>T p.P1163= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs758300066, COSV60300411; called by muse, mutect2, varscan2
